Somatic mutation profile of tumor specimen TCGA-13-0910-01A (aliquot TCGA-13-0910-01A-01W-0421-09) from TCGA case TCGA-13-0910, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 58.8 years (21,473 days).
Specimen TCGA-13-0910-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0a4d538-07b9-448b-8d8c-f414ff482ba2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0910-10A (Blood Derived Normal), aliquot TCGA-13-0910-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d416e4d-bfa7-4dd0-a785-eda4e4e8696b

The open-access MAF lists 49 somatic variants for this specimen: 42 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 35, Silent 7, Frame Shift Ins 4, Splice Site 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL11A2 | c.966dup p.T323Hfs*19 | Frame Shift Ins (INS) | VAF 5/16 reads (31%) | catalogued as rs748440351; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 50/80 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS20 | c.4016C>G p.A1339G | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV67134156; called by muse, mutect2, varscan2
- ADGRV1 | c.1787T>A p.L596* | Nonsense Mutation (SNP) | VAF 83/181 reads (46%) | catalogued as COSV67988712; called by muse, mutect2, varscan2
- ADRA2B | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1169533868, COSV69787749; called by muse, mutect2, varscan2
- ARHGAP33 | c.387dup p.E130Rfs*27 | Frame Shift Ins (INS) | VAF 6/52 reads (12%) | catalogued as rs772293323; called by mutect2, pindel
- ARHGAP35 | c.1467_1468del p.E490Rfs*15 | Frame Shift Del (DEL) | VAF 71/213 reads (33%) | catalogued as COSV68331685; called by mutect2, pindel, varscan2
- ARMC12 | c.491C>T p.T164M (on ENST00000373866 / NM_001286574.2; = p.T191M on NM_145028.5) | Missense Mutation (SNP) | VAF 190/266 reads (71%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs372805979; called by muse, mutect2, varscan2
- ARNTL2 | c.967T>C p.W323R | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53826809; called by muse, mutect2
- ASCC3 | c.4846A>G p.I1616V | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as rs753875786, COSV64977162; called by muse, mutect2, varscan2
- B4GALT2 | c.761T>G p.F254C | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58844441; called by muse, mutect2, varscan2
- BCHE | c.1395G>T p.M465I | Missense Mutation (SNP) | VAF 117/382 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.059); catalogued as COSV52258509; called by muse, mutect2, varscan2
- CDC14B | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99685401; called by muse, mutect2
- CFAP46 | c.7142G>T p.R2381I | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as COSV99584143; called by muse, mutect2, varscan2
- HCRTR2 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs141639071, COSV63793586, COSV63794792; called by muse, mutect2, varscan2
- LRRC8C | c.1524dup p.W509Lfs*20 | Frame Shift Ins (INS) | VAF 17/147 reads (12%) | catalogued as rs762972819; called by mutect2, varscan2
- LTBP1 | c.2081C>T p.S694F (on ENST00000404816 / NM_206943.4; = p.S368F on NM_000627.4) | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV63191020; called by muse, mutect2, varscan2
- MED12L | c.6212C>T p.P2071L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.041); catalogued as COSV99851955; called by mutect2, varscan2
- MS4A15 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs781231770, COSV61960993; called by muse, mutect2, varscan2
- NRROS | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs776104305, COSV60746558; called by muse, mutect2, varscan2
- PLK2 | c.895A>G p.M299V | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as rs1477447806; called by muse, mutect2, varscan2
- PRKAR1B | c.441T>G p.S147R | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV100816564; called by muse, mutect2, varscan2
- PRMT2 | c.485G>T p.R162I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV99388550; called by muse, mutect2, varscan2
- PRSS55 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 54/222 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100153681, COSV60808651; called by muse, mutect2, varscan2
- PTPRO | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs752358724, COSV55512609; called by muse, mutect2, varscan2
- PYHIN1 | c.1353C>G p.F451L | Missense Mutation (SNP) | VAF 118/336 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV63722973; called by muse, mutect2, varscan2
- RARS1 | c.1022G>C p.R341T | Missense Mutation (SNP) | VAF 116/285 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV51564447; called by muse, mutect2, varscan2
- RET | c.2340G>T p.K780N | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100392735; called by muse, mutect2
- RIMBP2 | c.2602C>A p.P868T | Missense Mutation (SNP) | VAF 13/244 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99898701; called by muse, mutect2
- SFMBT2 | c.2656G>T p.V886L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV62811916; called by muse, mutect2, varscan2
- SLC66A1 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100913181; called by muse, mutect2
- SYT2 | c.1257G>C p.K419N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV100937125; called by muse, mutect2
- TOM1L1 | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 158/220 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61948260; called by muse, mutect2, varscan2
- ZBTB21 | c.2755A>C p.T919P | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV60404706; called by muse, mutect2, varscan2
- ZNF384 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 82/423 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs968023019, COSV100158254; called by muse, varscan2
- BRD8 | c.3683T>C p.V1228A | Missense Mutation (SNP) | VAF 15/341 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2
- BRDT | c.1460+2T>A p.X487_splice | Splice Site (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- CHM | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- DLGAP5 | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2
- JAK2 | c.2735dup p.Y913Vfs*12 | Frame Shift Ins (INS) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- KALRN | c.6519G>C p.R2173S (on ENST00000360013 / NM_001024660.4; = p.R476S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2
- NUDT9 | c.689A>T p.E230V | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP2B1 | c.3087A>G p.K1029= | Silent (SNP) | VAF 78/255 reads (31%) | catalogued as COSV53809518; called by muse, mutect2, varscan2
- KLHL32 | c.456C>T p.D152= | Silent (SNP) | VAF 97/202 reads (48%) | catalogued as rs1326091926, COSV65110839; called by muse, mutect2, varscan2
- LILRB4 | c.1239C>T p.Y413= (on ENST00000391733 / NM_001278428.3; = p.Y412= on NM_001278426.3) | Silent (SNP) | VAF 26/106 reads (25%) | catalogued as rs191773308; called by muse, mutect2
- MED12L | c.5109C>T p.Y1703= | Silent (SNP) | VAF 68/241 reads (28%) | catalogued as rs767901074, COSV56377792; called by muse, mutect2, varscan2
- PRDM9 | c.1959T>C p.T653= | Silent (SNP) | VAF 82/293 reads (28%) | catalogued as rs565855433, COSV57008547; called by muse, varscan2
- TRPC7 | c.504C>T p.I168= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs1178142311, COSV61462917; called by muse, mutect2, varscan2
- ZNF711 | c.714G>A p.G238= | Silent (SNP) | VAF 47/80 reads (59%) | catalogued as COSV52156138; called by muse, mutect2, varscan2
